TCGA case TCGA-AG-3881 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6ba7313-8e91-4c39-8629-db3e96f4c556

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C80.1; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 83.4 years (30,467 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 579 days (1.6 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 30; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 579 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 16 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-3881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-AG-3881-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-AG-3881-01A-01-TS1: Section location: Top; Percent tumor cells: 47; Percent tumor nuclei: 65; Percent normal cells: 53; Percent necrosis: 1; Percent stromal cells: 2.
- Sample TCGA-AG-3881-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AG-3881-10A, TCGA-AG-3881-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Rectum; Lymph nodes examined: Yes; CEA level pretreatment: 16; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 579 days; disease-specific survival: no event (censored), 579 days; progression-free interval: no event (censored), 579 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AG-3881-01A-01D-0903-01): tumor purity 0.67, ploidy 2.74, whole-genome doublings 1.
